Somatic mutation profile of tumor specimen TCGA-B6-A0X0-01A (aliquot TCGA-B6-A0X0-01A-21D-A10Y-09) from TCGA case TCGA-B6-A0X0, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cribriform carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 54.2 years (19,802 days).
Specimen TCGA-B6-A0X0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a2b964e-8d5c-491b-9ee6-d3e0c94c9e89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0X0-10A (Blood Derived Normal), aliquot TCGA-B6-A0X0-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a72e4ac8-8dc7-40ff-a7ff-52a253892ecb

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRMPD4 | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); catalogued as COSV66212135; called by muse, mutect2, varscan2
- GATA3 | c.922-3_922-2del p.X308_splice | Splice Site (DEL) | VAF 36/137 reads (26%) | catalogued as rs763236375, COSV60515023; called by mutect2, pindel, varscan2
- ITGB3 | c.1094A>G p.N365S | Missense Mutation (SNP) | VAF 126/353 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as CM153645, COSV71383541; called by muse, mutect2, varscan2
- LCP1 | c.236A>G p.H79R | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV59939867; called by muse, mutect2, varscan2
- LRP2 | c.1450G>T p.V484L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV55544307; called by muse, mutect2, varscan2
- MYO18A | c.1865A>G p.N622S | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.056); catalogued as rs1435208648, COSV62863570; called by muse, mutect2, varscan2
- NOTCH2 | c.4996G>T p.V1666F | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV104375199, COSV56684366; called by muse, mutect2, varscan2
- PCDH19 | c.466C>G p.P156A | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55258928; called by muse, mutect2, varscan2
- PHF20 | c.2249A>T p.Q750L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.728); catalogued as COSV64975044; called by muse, mutect2, varscan2
- SEH1L | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as rs767376115, COSV50816350; called by muse, mutect2, varscan2
- SH3D19 | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58789510; called by muse, mutect2, varscan2
- SLCO2A1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs148547180, CM147859, COSV60483787; called by muse, mutect2, varscan2
- STAT4 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 36/130 reads (28%) | catalogued as COSV61828430; called by muse, mutect2, varscan2
- RUNX1 | c.346_360del p.E116_A120del (on ENST00000344691 / NM_001001890.3; = p.E143_A147del on NM_001754.5) | In Frame Del (DEL) | VAF 53/183 reads (29%) | called by mutect2, pindel, varscan2
- ALAS2 | c.1041C>A p.S347= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as COSV100238385, COSV58188871; called by muse, mutect2, varscan2
- ASMTL | c.1752G>A p.E584= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV67243087; called by muse, mutect2, varscan2
- CDH6 | c.423C>T p.P141= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as rs1014165415, COSV54065691; called by muse, mutect2, varscan2
- MYPN | c.3519G>T p.V1173= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV62732040; called by muse, mutect2, varscan2
- OR5D16 | c.357G>A p.V119= | Silent (SNP) | VAF 9/218 reads (4%) | catalogued as COSV101003989, COSV65721452; called by muse, mutect2
- ZNF804B | c.2547T>C p.T849= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100303891, COSV60819606; called by muse, mutect2, varscan2
